Somatic mutation profile of tumor specimen MP2PRT-PAUVEW-TMP1-A (aliquot MP2PRT-PAUVEW-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUVEW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 3.9 years (1,414 days).
Specimen MP2PRT-PAUVEW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88925b76-326d-4daa-88e5-4b60b5f2607d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUVEW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUVEW-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b4e213a-86bb-4ea6-9394-52d2d447cb64

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Nonsense Mutation 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 70/211 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1709T>C p.L570P (on ENST00000521381 / NM_181523.3; = p.L300P on NM_181504.4) | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57123228, COSV57133965; called by muse, mutect2, varscan2
- PLA2R1 | c.4127T>C p.I1376T | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs761456799; called by muse, mutect2, varscan2
- PRDM5 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746598644; called by muse, mutect2, varscan2
- SALL3 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 212/943 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs755505029; called by muse, mutect2, varscan2
- TEX15 | c.2147G>A p.R716H (on ENST00000256246; = p.R1099H on NM_001350162.2) | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs748586725; called by muse, mutect2, varscan2
- BHMT | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 118/263 reads (45%) | called by muse, mutect2, varscan2
- CFAP46 | c.1314_1315insAAG p.D438_E439insK | In Frame Ins (INS) | VAF 103/432 reads (24%) | called by mutect2, pindel, varscan2
- LRRC37A3 | c.3953C>T p.T1318I | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MAGEC3 | c.1724T>C p.I575T | Missense Mutation (SNP) | VAF 132/292 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- MYOM3 | c.1804C>T p.L602F | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.534); called by muse, mutect2
- CCDC40 | c.1221C>T p.I407= | Silent (SNP) | VAF 78/230 reads (34%) | catalogued as rs760734578, COSV53899386; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.459C>T p.T153= | Silent (SNP) | VAF 40/159 reads (25%) | catalogued as rs191590262, COSV56756028; called by muse, mutect2, varscan2
- PEG3 | c.4101A>T p.A1367= | Silent (SNP) | VAF 94/284 reads (33%) | catalogued as COSV55625067; called by muse, mutect2, varscan2
- SVIL | c.5475G>A p.E1825= (on ENST00000355867 / NM_021738.3; = p.E1399= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 113/451 reads (25%) | catalogued as rs1180829415; called by muse, mutect2, varscan2
- TMEM107 | c.*679G>A | 3'UTR (SNP) | VAF 78/216 reads (36%) | catalogued as rs769037861; called by muse, mutect2
